Gene-level copy-number profile of tumor specimen TCGA-B0-4690-01A from TCGA case TCGA-B0-4690, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 65.7 years (23,985 days).
Specimen TCGA-B0-4690-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.9c780ddd-5dcf-4bf0-bf31-c21c1d3d52f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B0-4690-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fa366311-0894-4a01-b6a0-8ae7a3473ab7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 278; copy number 2: 11,260; copy number 3: 29,497; copy number 4: 11,912; copy number 5: 3,680; copy number 6: 1,912; copy number 7: 1,102; copy number 8: 28; copy number 10: 22; copy number 11: 16; copy number 33: 27; copy number 42: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-B0-4690-01): tumor purity 0.37, ploidy 2.17, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:1,065,580–1,730,474, 5 genes: RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39.
- chr9:21,966,929–22,455,740, 10 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–2): PTEN.
- chr10:87,945,502–88,049,823, 3 genes: RPL11P3, AC063965.1, MED6P1.
- chr10:111,498,191–111,498,941, 1 gene: RPS6P15.
- chr11:112,959,279–114,414,203, 34 genes (within-gene range 0–2): AP000802.1, NCAM1, RNU7-187P, NCAM1-AS1, AP000880.1, TTC12, AP002840.2, ANKK1, AP002840.1, DRD2, MIR4301, TMPRSS5, MTRF1LP1, ZW10, RPS29P19, AP003170.5, AP003170.4, CLDN25, ATF4P4, AP003170.2, LRRC37A13P, USP28, AP003170.3, AP003170.1, RNU6-1107P, HTR3B, HTR3A, ZBTB16, AP002755.1, AP002518.2, NNMT, AP002518.1, C11orf71, RBM7.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,217 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:104,487,095–105,588,802, 17 genes, copy number 8: AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1.
- chr6:106,045,423–107,459,564, 26 genes, copy number 8–11 (within-gene range 2–11): ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr6:107,509,803–107,511,721, 1 gene, copy number 11: AL121957.1.
- chr7:70,972–54,455,093, 925 genes, copy number 7 (broad region; genes not listed).
- chr7:128,207,872–135,510,127, 177 genes, copy number 7 (broad region; genes not listed).
- chr15:89,041,223–90,502,239, 71 genes, copy number 10–42 (within-gene range 3–42) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 271. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
